Somatic mutation profile of tumor specimen MMRF_2660_1_BM_CD138pos (aliquot MMRF_2660_1_BM_CD138pos_T1_KHS5U_L13778) from MMRF case MMRF_2660, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.6 years (14,108 days).
Specimen MMRF_2660_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eb8fdc9-83a9-4afb-b19b-f25de91a9c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2660_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2660_1_PB_WBC_C3_KHS5U_L13779; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58286118-6679-4fe0-a5f1-c4093f6b7838

The open-access MAF lists 106 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 28, Missense Mutation 27, Intron 15, Silent 12, 5'UTR 5, 5'Flank 5, 3'Flank 4, Nonsense Mutation 3, RNA 3, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764260441; called by muse, mutect2, varscan2
- ARAF | c.640T>A p.S214T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV51691221, COSV51692725, COSV51695605; called by muse, mutect2
- CACNA1S | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs545411173, COSV62943438; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- COL4A4 | c.4710G>T p.E1570D | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1443445766; called by muse, mutect2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 92/152 reads (61%) | catalogued as rs750161916; called by mutect2, varscan2
- CRP | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 14/278 reads (5%) | catalogued as COSV54814296; called by muse, mutect2
- DNAH8 | c.5843C>T p.T1948M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199517916; called by muse, mutect2, varscan2
- FANCF | c.78G>A p.W26* | Nonsense Mutation (SNP) | VAF 69/142 reads (49%) | catalogued as COSV59416226; called by muse, mutect2, varscan2
- KRAS | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55736632, COSV55745894; called by muse, mutect2, varscan2
- MLANA | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 512/851 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101199966; called by muse, mutect2, varscan2
- MNT | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs1379344508; called by muse, mutect2
- NPAP1 | c.2896G>A p.G966S | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs781003390; called by muse, mutect2, varscan2
- OSTN | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.569); catalogued as COSV100174315; called by muse, mutect2, varscan2
- PCDHB6 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs891979677, COSV50689851, COSV50706884; called by muse, mutect2, varscan2
- PLA2G1B | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 21/502 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs143788130, COSV100387541; called by muse, mutect2
- RUBCNL | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 182/425 reads (43%) | catalogued as rs375541525; called by muse, mutect2, varscan2
- SERPINB4 | c.-26-1G>T | Splice Site (SNP) | VAF 189/470 reads (40%) | catalogued as COSV61986026; called by muse, mutect2, varscan2
- THBS1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs956814071; called by muse, mutect2
- TNR | c.3648del p.H1216Qfs*42 | Frame Shift Del (DEL) | VAF 73/196 reads (37%) | catalogued as COSV99689538; called by mutect2, pindel, varscan2
- TTC39A | c.1411G>A p.G471R (on ENST00000447632 / NM_001297665.1; = p.G436R on NM_001080494.3) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as rs1484889005; called by muse, mutect2, varscan2
- ACOD1 | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADNP | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2
- CRYBG2 | c.4038+6T>A | Splice Region (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- HADHB | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IGLC2 | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- MYH2 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA25 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- OR5AU1 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- RAPGEF5 | c.520A>C p.T174P (on ENST00000401957 / NM_001367602.2; = p.T477P on NM_012294.5) | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SOGA1 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SVEP1 | c.7078G>T p.V2360F | Missense Mutation (SNP) | VAF 103/180 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SYNE2 | c.13588G>A p.D4530N | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TDRD9 | c.2852G>T p.C951F | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- WNT5B | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AREG | c.150G>A p.E50= | Silent (SNP) | VAF 24/334 reads (7%) | called by muse, mutect2
- C3orf70 | c.612C>T p.D204= | Silent (SNP) | VAF 237/363 reads (65%) | catalogued as rs779811600, COSV58591432; called by muse, mutect2, varscan2
- CYP2U1 | c.1362C>A p.A454= | Silent (SNP) | VAF 68/170 reads (40%) | catalogued as COSV60549813; called by muse, mutect2, varscan2
- GDAP1 | c.735C>G p.T245= | Silent (SNP) | VAF 65/180 reads (36%) | catalogued as rs755020721; called by muse, mutect2, varscan2
- IGHV2-70 | c.129C>T p.F43= | Silent (SNP) | VAF 90/128 reads (70%) | catalogued as rs548066677; called by muse, varscan2
- NLN | c.1956A>G p.K652= | Silent (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- PAPPA | c.21G>A p.V7= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- PGAM2 | c.666G>A p.K222= | Silent (SNP) | VAF 145/554 reads (26%) | called by muse, mutect2, varscan2
- PKD1L1 | c.5005A>C p.R1669= | Silent (SNP) | VAF 89/256 reads (35%) | called by muse, mutect2, varscan2
- SHC3 | c.126G>A p.A42= | Silent (SNP) | VAF 74/259 reads (29%) | called by muse, mutect2, varscan2
- VANGL1 | c.660G>A p.V220= | Silent (SNP) | VAF 13/197 reads (7%) | called by muse, mutect2
- ZC3H18 | c.2458C>T p.L820= | Silent (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- AACS | c.1423+323T>C | Intron (SNP) | VAF 65/155 reads (42%) | called by muse, mutect2, varscan2
- ACSL5 | c.*296C>T | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ACTR3 | c.*3267G>A | 3'UTR (SNP) | VAF 6/146 reads (4%) | catalogued as rs894773037; called by muse, mutect2
- AKAP10 | c.*40_*41del | 3'UTR (DEL) | VAF 190/579 reads (33%) | called by mutect2, pindel, varscan2
- ALDH1L1 | c.858+139A>C | Intron (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2
- ANKH | c.-121del | 5'UTR (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65499534 C>G | 5'Flank (SNP) | VAF 58/168 reads (35%) | catalogued as rs377353346; called by muse, mutect2, varscan2
- BAX | c.234-30C>A | Intron (SNP) | VAF 74/183 reads (40%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021303 C>G | 5'Flank (SNP) | VAF 71/157 reads (45%) | catalogued as rs563776606; called by muse, mutect2, varscan2
- BCL7A | chr12:122021425 G>A | 5'Flank (SNP) | VAF 102/217 reads (47%) | called by muse, varscan2
- C8orf34-AS1 | n.448-102T>A | Intron (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- CCHCR1 | c.-51-13T>G | Intron (SNP) | VAF 32/688 reads (5%) | called by muse, mutect2
- CDC37L1 | c.*1685A>C | 3'UTR (SNP) | VAF 41/173 reads (24%) | catalogued as rs1367596164; called by muse, mutect2, varscan2
- CDH8 | c.1536+145G>A | Intron (SNP) | VAF 26/60 reads (43%) | catalogued as COSV54910886; called by muse, mutect2, varscan2
- CNTN4 | c.*918G>T | 3'UTR (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- DAPK3 | c.828+181C>T | Intron (SNP) | VAF 10/31 reads (32%) | catalogued as rs934661778; called by muse, varscan2
- DHRS7B | c.-41T>G | 5'UTR (SNP) | VAF 72/189 reads (38%) | catalogued as rs375926496; called by muse, mutect2, varscan2
- DMRT1 | c.*854A>G | 3'UTR (SNP) | VAF 29/99 reads (29%) | catalogued as rs1348313665; called by muse, mutect2, varscan2
- DSCAM | c.*914C>T | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161899365 G>T | 3'Flank (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- GABRA6 | c.*62A>C | 3'UTR (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- GET4 | c.155+1214C>G | Intron (SNP) | VAF 49/167 reads (29%) | called by muse, mutect2, varscan2
- GLCCI1 | c.-104del | 5'UTR (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- GRIK3 | c.*617A>G | 3'UTR (SNP) | VAF 117/252 reads (46%) | called by muse, mutect2, varscan2
- H2BC21 | c.*209G>A | 3'UTR (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- HADH | c.133-4853A>G | Intron (SNP) | VAF 69/157 reads (44%) | catalogued as rs1044389670; called by muse, mutect2, varscan2
- HDAC2 | c.*175T>G | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- HOXC9 | c.*357T>C | 3'UTR (SNP) | VAF 50/95 reads (53%) | catalogued as rs1347521135; called by muse, mutect2, varscan2
- HTRA3 | c.*135G>A | 3'UTR (SNP) | VAF 49/111 reads (44%) | catalogued as rs1230604815; called by muse, mutect2, varscan2
- IGHM | chr14:105859505 C>G | 5'Flank (SNP) | VAF 6/8 reads (75%) | catalogued as rs112591860; called by muse, mutect2
- IGLC2 | c.*11C>T | 3'UTR (SNP) | VAF 71/333 reads (21%) | catalogued as rs15051; called by muse, mutect2, varscan2
- IGLL5 | chr22:22899481 G>A | 3'Flank (SNP) | VAF 38/44 reads (86%) | called by muse, mutect2
- KMT5B | c.*689A>G | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- LDAH | c.*1706T>A | 3'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- LENG8 | c.*2775A>G | 3'UTR (SNP) | VAF 247/520 reads (48%) | called by muse, mutect2, varscan2
- LINC00602 | n.965del | RNA (DEL) | VAF 79/199 reads (40%) | called by mutect2, pindel, varscan2
- LRRC56 | c.*331G>A | 3'UTR (SNP) | VAF 64/143 reads (45%) | catalogued as rs1000454829; called by muse, mutect2, varscan2
- LRRIQ3 | c.*334G>T | 3'UTR (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- LYPD1 | c.*381G>T | 3'UTR (SNP) | VAF 80/163 reads (49%) | called by muse, mutect2, varscan2
- MAP4 | chr3:47851172 C>T | 3'Flank (SNP) | VAF 148/299 reads (49%) | called by muse, mutect2, varscan2
- NFIL3 | c.-43A>C | 5'UTR (SNP) | VAF 32/754 reads (4%) | called by muse, mutect2
- NPEPL1 | chr20:58717776 C>G | 3'Flank (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- PBXIP1 | c.*756C>T | 3'UTR (SNP) | VAF 88/188 reads (47%) | called by muse, mutect2, varscan2
- PDE2A | c.1359+59G>A | Intron (SNP) | VAF 86/207 reads (42%) | called by muse, mutect2, varscan2
- PPA2 | c.222+11G>A | Intron (SNP) | VAF 104/230 reads (45%) | catalogued as rs769566971; called by muse, mutect2, varscan2
- RACK1 | c.109+527T>G | Intron (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-623C>T | Intron (SNP) | VAF 40/108 reads (37%) | catalogued as rs1041355135; called by muse, mutect2, varscan2
- RIOK3 | c.*1249A>C | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs1026944328, COSV59771904; called by muse, mutect2, varscan2
- RNF41 | c.*786T>G | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- SLC6A10P | n.1312A>T | RNA (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- SLC6A10P | n.1311G>A | RNA (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- SNTB2 | c.*771T>A | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- SRRM3 | c.1008+153T>C | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- SSTR4 | c.*74G>A | 3'UTR (SNP) | VAF 103/258 reads (40%) | called by muse, mutect2, varscan2
- SYT10 | c.*2210_*2213dup | 3'UTR (INS) | VAF 43/100 reads (43%) | called by mutect2, pindel, varscan2
- TCERG1 | c.*417A>T | 3'UTR (SNP) | VAF 8/80 reads (10%) | catalogued as rs1012736223, COSV57033522; called by muse, mutect2
- TMSB4X | chrX:12975330 T>C | 5'Flank (SNP) | VAF 115/121 reads (95%) | called by muse, mutect2, varscan2
- UNC5C | c.*4514G>A | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- VAX1 | c.-38T>C | 5'UTR (SNP) | VAF 22/60 reads (37%) | catalogued as COSV53327526; called by mutect2, varscan2
- VPS53 | c.609-1196A>T | Intron (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
